Gene-level copy-number profile of specimen HCM-BROD-0415-C71-85R from HCMI case HCM-BROD-0415-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.3 years (19,455 days).
Specimen HCM-BROD-0415-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a633652a-6618-406a-baa3-491ae02fda32.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0415-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/c290f882-3cd2-4fa3-93df-8109d05d3bad

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,467; copy number 3: 5,902; copy number 4: 36,369; copy number 5: 6,756; copy number 6: 4,848; copy number 7: 28; copy number 8: 15; copy number 10: 16.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:3,976,056–4,323,843, 16 genes, copy number 10: EEF2, SNORD37, PIAS4, ZBTB7A, AC016586.1, MAP2K2, Metazoa_SRP, CREB3L3, SIRT6, ANKRD24, EBI3, AC005578.1, YJU2, SHD, TMIGD2, FSD1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
